Somatic mutation profile of tumor specimen TCGA-CV-A45V-01A (aliquot TCGA-CV-A45V-01A-21D-A25D-08) from TCGA case TCGA-CV-A45V, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Mouth, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G1; Age at diagnosis: 87.4 years (31,936 days).
Specimen TCGA-CV-A45V-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b833e647-65c5-486b-961c-ec0834ed6873.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CV-A45V-10A (Blood Derived Normal), aliquot TCGA-CV-A45V-10A-01D-A25E-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d9be5641-26fc-4b8e-ba68-7ae4af6a2846

The open-access MAF lists 120 somatic variants for this specimen: 87 protein-altering or splice-affecting, 31 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 71, Silent 31, Frame Shift Ins 6, Nonsense Mutation 4, Frame Shift Del 3, Splice Site 2, RNA 1, Splice Region 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1513C>G p.R505G (on ENST00000281708 / NM_001349798.2; = p.R425G on NM_018315.5) | Missense Mutation (SNP) | VAF 14/101 reads (14%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs149680468, COSV55890969, COSV55891274, COSV55898451; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KANSL1 | c.1652+1G>A p.X551_splice | Splice Site (SNP) | VAF 15/73 reads (21%) | catalogued as rs281865470, CS124331, COSV52267422, COSV52272538; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KMT2D | c.6844del p.R2282Gfs*4 | Frame Shift Del (DEL) | VAF 7/42 reads (17%) | catalogued as rs1555192531, CD160608, COSV99979404; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 12/46 reads (26%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCC9 | c.666G>T p.L222F | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.488); catalogued as COSV99685436; called by muse, mutect2, varscan2
- ABTB1 | c.1240C>T p.R414W (on ENST00000232744 / NM_172027.3; = p.R272W on NM_032548.3) | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.328); catalogued as rs766190220; called by muse, mutect2, varscan2
- AC013477.1 | c.2100G>C p.K700N | Missense Mutation (SNP) | VAF 36/70 reads (51%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.015); catalogued as COSV53654382, COSV99548801; called by muse, mutect2, varscan2
- ACTL8 | c.862C>T p.R288C | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.765); catalogued as rs375817792; called by muse, mutect2, varscan2
- AGTPBP1 | c.3526G>A p.E1176K (on ENST00000357081 / NM_001330701.2; = p.E1136K on NM_015239.2) | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs1287483960, COSV100429636; called by muse, mutect2, varscan2
- AK5 | c.1505G>A p.R502Q (on ENST00000354567 / NM_174858.3; = p.R476Q on NM_012093.4) | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as rs373612539; called by muse, mutect2, varscan2
- ARID4A | c.3698C>T p.S1233F | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100794176; called by muse, mutect2
- ATRNL1 | c.1390G>T p.V464L | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.058); catalogued as COSV100745007; called by muse, mutect2, varscan2
- BCL6 | c.280C>T p.R94W | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.998); catalogued as rs781532443, COSV51656438; called by muse, mutect2, varscan2
- CACNA2D1 | c.31C>G p.L11V | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.899); catalogued as COSV100667286, COSV62372193; called by muse, mutect2, varscan2
- CASP8 | c.910C>G p.H304D (on ENST00000432109 / NM_033355.3; = p.H321D on NM_001228.4) | Missense Mutation (SNP) | VAF 20/119 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV99630136; called by muse, mutect2, varscan2
- CD44 | c.859G>A p.D287N | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.227); catalogued as COSV99555677; called by muse, mutect2
- CFAP46 | c.6415C>A p.Q2139K | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as COSV99584523; called by muse, mutect2, varscan2
- CLU | c.413G>A p.R138H | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT tolerated (0.29); PolyPhen benign (0.017); catalogued as rs756208273, COSV100324259, COSV100324464; called by muse, mutect2, varscan2
- COL22A1 | c.535G>A p.E179K | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as rs779147504, COSV100276767, COSV57368448; called by muse, mutect2, varscan2
- CTCF | c.1037C>G p.T346S | Missense Mutation (SNP) | VAF 47/209 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV50491934, COSV99865100; called by muse, mutect2, varscan2
- DDX31 | c.1954G>A p.E652K | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as COSV100936731; called by muse, mutect2
- DLAT | c.1161G>C p.K387N | Missense Mutation (SNP) | VAF 43/154 reads (28%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.856); catalogued as COSV99734628; called by muse, mutect2, varscan2
- DNAJC5G | c.319C>T p.H107Y | Missense Mutation (SNP) | VAF 6/91 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.255); catalogued as COSV56079580; called by muse, mutect2
- DST | c.3644T>G p.L1215* (on ENST00000361203 / NM_001374722.1; = p.L889* on NM_001723.6) | Nonsense Mutation (SNP) | VAF 18/81 reads (22%) | catalogued as COSV99754636; called by muse, mutect2, varscan2
- ENGASE | c.2018C>T p.S673F | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.364); catalogued as COSV56133737; called by muse, mutect2, varscan2
- ESAM | c.839A>G p.E280G | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); catalogued as COSV99631753; called by muse, mutect2, varscan2
- FAM135A | c.446A>C p.H149P (on ENST00000370479 / NM_001351599.1; = p.H106P on NM_020819.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99525650; called by muse, mutect2, varscan2
- FAM24A | c.238C>T p.Q80* | Nonsense Mutation (SNP) | VAF 23/82 reads (28%) | catalogued as COSV100925079; called by muse, mutect2, varscan2
- FAT1 | c.12408C>G p.C4136W | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101499296; called by muse, mutect2, varscan2
- FLG | c.680G>A p.W227* | Nonsense Mutation (SNP) | VAF 20/110 reads (18%) | catalogued as COSV100911483; called by muse, mutect2, varscan2
- GLRA4 | c.379A>T p.I127F | Missense Mutation (SNP) | VAF 40/161 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.6); catalogued as COSV101009626, COSV65456783; called by muse, mutect2, varscan2
- GPRASP2 | c.1940T>A p.L647H | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100176686; called by muse, mutect2, varscan2
- HAL | c.1942T>A p.S648T | Missense Mutation (SNP) | VAF 32/125 reads (26%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0.003); catalogued as COSV99701344; called by muse, mutect2, varscan2
- HDX | c.1328G>C p.S443T | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99947119; called by muse, mutect2, varscan2
- HEMGN | c.948A>C p.Q316H | Missense Mutation (SNP) | VAF 32/165 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.337); catalogued as COSV99412367; called by muse, mutect2, varscan2
- HLX | c.673G>A p.A225T | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.04); catalogued as COSV65044463; called by muse, mutect2, varscan2
- HSD11B2 | c.374G>A p.R125H | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs781679176, COSV99341106; called by muse, mutect2, varscan2
- IL18RAP | c.1145A>G p.Y382C | Missense Mutation (SNP) | VAF 38/161 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.029); catalogued as COSV99961921; called by muse, mutect2, varscan2
- ITGA7 | c.2090G>A p.R697H (on ENST00000555728; = p.R653H on NM_002206.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.013); catalogued as COSV99145336; called by muse, mutect2
- ITPR2 | c.4005G>A p.L1335= | Splice Region (SNP) | VAF 27/122 reads (22%) | catalogued as COSV101189944; called by muse, mutect2, varscan2
- KIAA1522 | c.133C>T p.H45Y (on ENST00000373480 / NM_001198972.2; = p.H104Y on NM_020888.3) | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT tolerated (0.81); PolyPhen benign (0.015); catalogued as COSV99614512; called by muse, mutect2, varscan2
- KIF15 | c.3857G>A p.R1286K | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV100392777; called by muse, mutect2, varscan2
- MAGEC3 | c.929G>A p.G310E | Missense Mutation (SNP) | VAF 43/130 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.379); catalogued as COSV100025265; called by muse, mutect2, varscan2
- MARK4 | c.1948G>A p.E650K (on ENST00000262891 / NM_001199867.2; = p.R676= on NM_031417.4) | Missense Mutation (SNP) | VAF 30/227 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.054); catalogued as COSV99488218; called by muse, mutect2, varscan2
- MBTPS1 | c.380C>T p.T127M | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.927); catalogued as rs142980972; called by muse, mutect2, varscan2
- MDGA2 | c.1481G>C p.G494A (on ENST00000399232 / NM_001113498.2; = p.G196A on NM_182830.4) | Missense Mutation (SNP) | VAF 26/145 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.306); catalogued as COSV100636929; called by muse, mutect2, varscan2
- MED1 | c.1879C>G p.H627D | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.121); catalogued as COSV100327727; called by muse, mutect2, varscan2
- MED13L | c.1930G>T p.A644S | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.6); PolyPhen benign (0.01); catalogued as COSV99928558; called by muse, mutect2, varscan2
- MINDY4 | c.1037C>T p.A346V | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.022); catalogued as rs1303043262, COSV99518528; called by muse, mutect2, varscan2
- MUC16 | c.37465G>A p.E12489K | Missense Mutation (SNP) | VAF 40/180 reads (22%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.014); catalogued as COSV101199521; called by muse, mutect2, varscan2
- MYC | c.437C>T p.S146L (on ENST00000377970; = p.S161L on NM_002467.6) | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV52367052; called by muse, mutect2, varscan2
- NCAM2 | c.87A>C p.K29N | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99522653; called by muse, mutect2
- NCAPD3 | c.1553A>G p.N518S | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV101599348; called by muse, mutect2, varscan2
- NLRP1 | c.1010G>C p.G337A | Missense Mutation (SNP) | VAF 37/179 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99332930, COSV99333861; called by muse, mutect2, varscan2
- NOTCH1 | c.2938T>G p.C980G | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99487205; called by muse, mutect2, varscan2
- OR11H1 | c.658G>T p.G220* | Nonsense Mutation (SNP) | VAF 27/151 reads (18%) | catalogued as COSV53271757; called by muse, mutect2, varscan2
- OR2B6 | c.571G>C p.E191Q | Missense Mutation (SNP) | VAF 38/163 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.18); catalogued as rs1321541031, COSV55128830, COSV99773718; called by muse, mutect2, varscan2
- PCDHB6 | c.2228T>C p.L743P | Missense Mutation (SNP) | VAF 70/170 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV99170079; called by muse, mutect2, varscan2
- PDGFRL | c.572A>T p.Q191L | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.142); catalogued as rs1411840869, COSV99286309; called by muse, mutect2, varscan2
- POLR3F | c.910C>T p.P304S | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV100464012; called by muse, mutect2
- PSCA | c.313G>T p.G105C | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.682); catalogued as rs782076248, COSV100008228, COSV56653048; called by muse, mutect2, varscan2
- RAPGEF4 | c.1315C>G p.R439G | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.615); catalogued as COSV99910409; called by muse, mutect2, varscan2
- REM1 | c.602G>A p.R201H | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199660041, COSV52427586; called by muse, mutect2, varscan2
- RNF217 | c.284C>G p.P95R | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.95); catalogued as rs953856907, COSV101451355; called by muse, mutect2
- ROM1 | c.1003G>A p.E335K | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT tolerated (0.37); PolyPhen benign (0.011); catalogued as COSV99605873; called by muse, mutect2, varscan2
- RPL27 | c.358G>C p.E120Q | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.566); catalogued as COSV99518479; called by muse, mutect2, varscan2
- SIGLEC11 | c.1958G>A p.R653K | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.28); PolyPhen benign (0.01); catalogued as rs1306665400, COSV101357062; called by muse, mutect2, varscan2
- SLC6A17 | c.2021G>A p.R674H | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.655); catalogued as rs796052160, COSV58992668; ClinVar: likely benign; called by muse, mutect2, varscan2
- SP140L | c.1255G>A p.D419N | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs747016700, COSV99707074; called by muse, mutect2, varscan2
- SPANXN3 | c.268G>T p.D90Y | Missense Mutation (SNP) | VAF 31/177 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.715); catalogued as rs782105135, COSV100980789, COSV65140299; called by muse, mutect2, varscan2
- STXBP5 | c.2054C>T p.P685L | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99470042; called by muse, mutect2, varscan2
- SUCO | c.1907G>T p.W636L | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as COSV99742615; called by muse, mutect2, varscan2
- TAFA2 | c.385-1G>T p.X129_splice | Splice Site (SNP) | VAF 28/111 reads (25%) | catalogued as rs371167984; called by muse, mutect2, varscan2
- TARDBP | c.739G>A p.D247N | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.677); catalogued as COSV99534144; called by muse, mutect2, varscan2
- TMTC1 | c.660G>C p.E220D (on ENST00000539277 / NM_001193451.2; = p.E112D on NM_175861.3) | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV55486040, COSV99759399; called by muse, mutect2, varscan2
- TNFSF10 | c.135G>A p.M45I | Missense Mutation (SNP) | VAF 23/116 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV99577676; called by muse, mutect2, varscan2
- TNNI2 | c.137C>T p.A46V | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.042); catalogued as rs753513106, COSV99425445; called by muse, mutect2, varscan2
- UGT1A6 | c.1468G>A p.V490M | Missense Mutation (SNP) | VAF 30/111 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747543462, COSV59387586; called by muse, mutect2, varscan2
- VIPAS39 | c.485G>A p.R162Q | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.042); catalogued as rs144078420, COSV100493034; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CASP8 | c.1241_1242del p.N414Tfs*24 (on ENST00000432109 / NM_033355.3; = p.N431Tfs*24 on NM_001228.4) | Frame Shift Del (DEL) | VAF 10/59 reads (17%) | called by mutect2, pindel, varscan2
- DCHS1 | c.2192dup p.L732Tfs*6 | Frame Shift Ins (INS) | VAF 24/105 reads (23%) | called by mutect2, varscan2
- DHRS1 | c.494_495del p.V165Gfs*6 | Frame Shift Del (DEL) | VAF 10/72 reads (14%) | called by pindel, varscan2
- FGFR4 | c.28dup p.V10Gfs*17 | Frame Shift Ins (INS) | VAF 8/28 reads (29%) | called by mutect2, pindel, varscan2
- KMT2C | c.12549dup p.S4184* | Frame Shift Ins (INS) | VAF 17/57 reads (30%) | called by mutect2, pindel, varscan2
- KMT2D | c.3730dup p.V1244Gfs*6 | Frame Shift Ins (INS) | VAF 21/101 reads (21%) | called by mutect2, pindel, varscan2
- MINK1 | c.2561dup p.R855Pfs*39 | Frame Shift Ins (INS) | VAF 4/23 reads (17%) | called by mutect2, pindel
- PDF | c.701dup p.N235Kfs*9 | Frame Shift Ins (INS) | VAF 27/151 reads (18%) | called by mutect2, pindel, varscan2
- CARM1 | c.876C>T p.V292= | Silent (SNP) | VAF 6/42 reads (14%) | catalogued as rs148487813; called by muse, mutect2, varscan2
- CNTNAP2 | c.2235C>T p.C745= | Silent (SNP) | VAF 6/27 reads (22%) | catalogued as rs773833579, COSV62152409; called by muse, mutect2, varscan2
- CYP1A1 | c.1203C>T p.I401= | Silent (SNP) | VAF 22/104 reads (21%) | catalogued as rs1371498900, COSV65698488; called by muse, mutect2, varscan2
- DDN | c.1353C>T p.G451= | Silent (SNP) | VAF 24/78 reads (31%) | catalogued as COSV100305074; called by muse, mutect2, varscan2
- DISP3 | c.9G>T p.T3= | Silent (SNP) | VAF 9/49 reads (18%) | catalogued as COSV99608308; called by muse, mutect2, varscan2
- DNAJB8 | c.243G>A p.T81= | Silent (SNP) | VAF 30/110 reads (27%) | catalogued as rs200983717, COSV59878721, COSV59878977; called by muse, mutect2, varscan2
- EHD3 | c.1044C>T p.I348= | Silent (SNP) | VAF 17/113 reads (15%) | catalogued as rs772559220, COSV100434681; called by muse, mutect2, varscan2
- EPHA10 | c.609G>A p.S203= | Silent (SNP) | VAF 9/47 reads (19%) | catalogued as rs767006722, COSV100139906; called by muse, mutect2, varscan2
- EPHA5 | c.1257C>T p.S419= | Silent (SNP) | VAF 6/58 reads (10%) | catalogued as rs753971619, COSV56631266, COSV56675035, COSV56676610; called by mutect2, varscan2
- EVI2B | c.348C>A p.S116= | Silent (SNP) | VAF 51/243 reads (21%) | catalogued as rs1426911482, COSV100445453; called by muse, mutect2, varscan2
- FLG | c.10932C>T p.H3644= | Silent (SNP) | VAF 107/541 reads (20%) | catalogued as rs369652769, COSV64243072; called by muse, mutect2, varscan2
- FSTL5 | c.690C>T p.D230= | Silent (SNP) | VAF 24/51 reads (47%) | catalogued as COSV100054465, COSV60217671; called by muse, mutect2, varscan2
- IQCN | c.2250A>G p.T750= | Silent (SNP) | VAF 34/118 reads (29%) | catalogued as COSV101148593; called by muse, mutect2, varscan2
- ITM2C | c.390C>T p.N130= | Silent (SNP) | VAF 25/121 reads (21%) | catalogued as rs560313566, COSV100419593; called by muse, mutect2, varscan2
- LRFN2 | c.42G>A p.A14= | Silent (SNP) | VAF 9/58 reads (16%) | catalogued as rs774848570, COSV100599460; called by muse, mutect2, varscan2
- LRRC4C | c.360C>T p.F120= | Silent (SNP) | VAF 14/53 reads (26%) | catalogued as COSV99537891; called by muse, mutect2, varscan2
- MYH8 | c.621G>A p.K207= | Silent (SNP) | VAF 25/87 reads (29%) | catalogued as COSV101238381; called by muse, mutect2, varscan2
- MYO7B | c.2304C>G p.L768= | Silent (SNP) | VAF 3/26 reads (12%) | catalogued as COSV101267832, COSV101268095; called by muse, mutect2
- NEK11 | c.1350C>T p.H450= | Silent (SNP) | VAF 22/109 reads (20%) | catalogued as rs369452144, COSV100797697; called by muse, mutect2, varscan2
- NLRP8 | c.987G>A p.T329= | Silent (SNP) | VAF 18/104 reads (17%) | catalogued as rs752969286, COSV52584745; called by muse, mutect2, varscan2
- OR10H2 | c.858C>G p.L286= | Silent (SNP) | VAF 18/84 reads (21%) | catalogued as COSV100008739; called by muse, mutect2, varscan2
- PDZRN3 | c.3181C>T p.L1061= | Silent (SNP) | VAF 22/109 reads (20%) | catalogued as COSV55214171; called by muse, mutect2, varscan2
- SIAH3 | c.702C>T p.C234= | Silent (SNP) | VAF 19/79 reads (24%) | catalogued as COSV101247819; called by muse, mutect2, varscan2
- SPIRE1 | c.1668C>T p.L556= (on ENST00000409402 / NM_001128626.2; = p.L542= on NM_020148.3) | Silent (SNP) | VAF 25/99 reads (25%) | catalogued as rs763662699, COSV100563475; called by muse, mutect2, varscan2
- TAS2R16 | c.438T>A p.I146= | Silent (SNP) | VAF 11/80 reads (14%) | catalogued as COSV99972231; called by muse, mutect2, varscan2
- TBL1X | c.1500G>A p.T500= | Silent (SNP) | VAF 10/39 reads (26%) | catalogued as rs759158876, COSV99482445; called by muse, mutect2, varscan2
- THOP1 | c.1875G>A p.T625= | Silent (SNP) | VAF 12/66 reads (18%) | catalogued as rs373236316; called by muse, mutect2, varscan2
- XIRP1 | c.1626G>A p.V542= | Silent (SNP) | VAF 14/91 reads (15%) | catalogued as rs937175474, COSV100453557; called by muse, mutect2, varscan2
- YIPF7 | c.237G>A p.E79= | Silent (SNP) | VAF 9/44 reads (20%) | catalogued as rs1489544624, COSV100274463; called by muse, mutect2, varscan2
- ZEB1 | c.999G>A p.E333= | Silent (SNP) | VAF 13/50 reads (26%) | catalogued as COSV100314184; called by muse, mutect2, varscan2
- ZSWIM4 | c.531G>A p.R177= | Silent (SNP) | VAF 3/47 reads (6%) | catalogued as rs1293273031; called by muse, mutect2
- C8orf86 | n.655G>A | RNA (SNP) | VAF 15/81 reads (19%) | catalogued as rs182509871, COSV63935244; called by muse, mutect2, varscan2
- PRPS1 | c.*3_*7del | 3'UTR (DEL) | VAF 18/100 reads (18%) | called by mutect2, pindel
